Somatic mutation profile of tumor specimen TARGET-15-SJMPAL041119-09A.2 (aliquot TARGET-15-SJMPAL041119-09A.2-01D) from TARGET case TARGET-15-SJMPAL041119, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,105 days).
Specimen TARGET-15-SJMPAL041119-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64ca041b-2deb-41ba-ab34-96bc872ffea9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL041119-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL041119-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88abe031-b0e1-49c1-8659-efb43eb3b98f

The open-access MAF lists 42 somatic variants for this specimen: 32 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 6, Nonsense Mutation 3, Intron 2, 3'UTR 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 100/206 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- C8A | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs755269006, COSV63485762; called by muse, mutect2, varscan2
- CD163L1 | c.848G>A p.W283* | Nonsense Mutation (SNP) | VAF 133/265 reads (50%) | catalogued as COSV99047110; called by muse, mutect2, varscan2
- CDHR5 | c.2090G>A p.G697D (on ENST00000358353 / NM_001171968.2; = p.G703D on NM_021924.5) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs767827381; called by muse, mutect2, varscan2
- CNNM1 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV63203328; called by muse, mutect2
- DNMBP | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60619983; called by muse, mutect2, varscan2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2, varscan2
- MUC19 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as rs754324589; called by muse, mutect2
- NADSYN1 | c.2070+1G>A p.X690_splice | Splice Site (SNP) | VAF 17/38 reads (45%) | catalogued as rs1555152822; called by muse, mutect2, varscan2
- RUNX1 | c.511G>A p.D171N (on ENST00000344691 / NM_001001890.3; = p.D198N on NM_001754.5) | Missense Mutation (SNP) | VAF 163/240 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as CM013280, CM1515470, COSV55868860, COSV55892672; called by muse, mutect2, varscan2
- SREBF2 | c.1457T>C p.V486A | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104419536; called by muse, mutect2
- AVL9 | c.1511G>A p.W504* | Nonsense Mutation (SNP) | VAF 9/113 reads (8%) | called by muse, mutect2
- BCAR1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- BTN2A1 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CHI3L2 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCHS1 | c.6029G>T p.G2010V | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- DCST2 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- DDX21 | c.1417C>A p.Q473K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- E4F1 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- HDX | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.97); called by muse, mutect2
- ITGA2 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 23/304 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.664); called by muse, mutect2
- KDELR3 | c.417C>A p.S139R | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- KIF16B | c.3444G>T p.M1148I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2
- MCAM | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCAM2 | c.1176C>A p.S392R | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCAPH2 | c.521C>A p.A174D | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- PLXNC1 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- RIF1 | c.3981C>A p.N1327K | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2
- SGPP2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SH3PXD2B | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STOX1 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 192/395 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.15); called by muse, varscan2
- TTN | c.86406G>A p.W28802* (on ENST00000591111; = p.W21378* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 57/195 reads (29%) | called by muse, mutect2, varscan2
- AHNAK | c.15639C>T p.P5213= | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- COL6A2 | c.3030C>T p.F1010= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV52428384; called by muse, mutect2, varscan2
- FCGR2A | c.804C>T p.A268= (on ENST00000271450 / NM_001136219.3; = p.A267= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/255 reads (20%) | catalogued as rs1341662703; called by muse, mutect2, varscan2
- KDELR1 | c.534C>T p.L178= | Silent (SNP) | VAF 77/139 reads (55%) | catalogued as COSV58102799; called by muse, varscan2
- NDST2 | c.522C>T p.A174= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2
- SVEP1 | c.228G>A p.R76= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs1188563743; called by muse, varscan2
- MPRIP | c.2164-2900C>A | Intron (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- PARP1 | c.2407-19C>T | Intron (SNP) | VAF 148/278 reads (53%) | called by muse, mutect2, varscan2
- TDRD3 | c.-121C>T | 5'UTR (SNP) | VAF 56/114 reads (49%) | catalogued as rs746076570; called by muse, mutect2, varscan2
- TUFT1 | c.*435C>T | 3'UTR (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
